Somatic mutation profile of tumor specimen 0DCDN5 from CCDI case PBBMKD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.2 years (1,891 days).
Specimen 0DCDN5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37555235-fd28-47a7-ad9e-e8f6c96ff851.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCDMV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c337cf4-03a4-499f-b4b8-a312c33a5ee5

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1B | c.1561dup p.Q521Pfs*30 | Frame Shift Ins (INS) | VAF 136/679 reads (20%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, varscan2
- HPCAL4 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 34/848 reads (4%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.785); catalogued as rs1478857861, COSV100864765; called by muse, mutect2
- SCN9A | c.5692C>T p.R1898C (on ENST00000303354; = p.R1887C on NM_002977.3) | Missense Mutation (SNP) | VAF 266/1452 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs577823520, COSV57619186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRED3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 27/640 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.296); catalogued as rs1360550580; called by muse, mutect2
- ACTN1 | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 45/1336 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- HMCN1 | c.3921G>T p.L1307F | Missense Mutation (SNP) | VAF 126/546 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by mutect2, varscan2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 62/1561 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 15/355 reads (4%) | called by muse, mutect2
- MEAK7 | c.-17G>T | 5'UTR (SNP) | VAF 16/332 reads (5%) | catalogued as COSV100640434; called by muse, mutect2
